CPTAC case C3N-00729 — Uterus, NOS — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a5422423-a260-4e1e-9b09-c8f4cab6abb5

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1930; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Corpus uteri; Age at diagnosis: 86.3 years (31,527 days); Year of diagnosis: 2016; AJCC staging edition: 8th; AJCC clinical M: MX; AJCC pathologic T: T1b; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IB; FIGO stage: Stage IB; Tumor grade: G2; Residual disease: RX; Last known disease status: With tumor; Days to last known disease status: 873 days (2.4 years); Progression or recurrence: yes; Days to recurrence: 820 days (2.2 years); Days to last follow up: 873 days (2.4 years); Tumor focality: Multifocal.
   Pathology details: Greatest tumor dimension: 4 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 4; Margin status: Uninvolved.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (4 entries)
- Days to follow up: 391 days (1.1 years); Disease response: With Tumor.
- Days to follow up: 720 days (2.0 years); Disease response: With Tumor.
- Days to follow up: 873 days (2.4 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 820 days (2.2 years).
- Days to follow up: 873 days (2.4 years); Disease response: With Tumor.

Other clinical attributes
- Weight: 80.74 kg; Height: 165.1 cm; BMI: 29.62.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (5 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-00729-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 0.122 mg.
- Sample C3N-00729-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 25 days; Initial weight: 145 mg; Time between excision and freezing: 18 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-00729-22: Section location: Both Anterior and Posterior; Percent tumor nuclei: 80; Percent necrosis: 0.
- Sample C3N-00729-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 25 days; Initial weight: 90 mg; Time between excision and freezing: 18 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-00729-23: Section location: Both Anterior and Posterior; Percent tumor nuclei: 90; Percent necrosis: 1.
- Sample C3N-00729-12: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 25 days; Time between excision and freezing: 18 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-00729-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 25 days; Method of sample procurement: Blood Draw.
